Somatic mutation profile of tumor specimen TCGA-22-5471-01A (aliquot TCGA-22-5471-01A-01D-1632-08) from TCGA case TCGA-22-5471, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.0 years (27,749 days).
Specimen TCGA-22-5471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e9447f1-24d7-4f92-bfe5-8d627b73e804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5471-11A (Solid Tissue Normal), aliquot TCGA-22-5471-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4c3e584-b984-4461-9698-03e0ba161394

The open-access MAF lists 238 somatic variants for this specimen: 184 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 49, Nonsense Mutation 19, Splice Site 5, Intron 4, Frame Shift Del 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.1760G>T p.R587L (on ENST00000326195 / NM_001025091.2; = p.R549L on NM_001090.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV58229481; called by muse, mutect2
- ADAD1 | c.529+1G>C p.X177_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56644335; called by muse, mutect2, varscan2
- ADAMTS16 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs763436374, COSV56993462, COSV56996747; called by muse, mutect2, varscan2
- ADCY8 | c.3077G>T p.R1026L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV53912309, COSV99650123; called by muse, mutect2, varscan2
- ADH1B | c.641C>A p.A214E | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV59296931, COSV59297444; called by muse, mutect2, varscan2
- AKAP13 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV63461427; called by muse, mutect2, varscan2
- ALX4 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV61327010; called by muse, mutect2, varscan2
- ANKK1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs771060056, COSV58272467; called by muse, mutect2, varscan2
- AOX1 | c.2257A>G p.M753V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV65982224; called by muse, mutect2, varscan2
- APOLD1 | c.731T>C p.L244P (on ENST00000326765 / NM_001130415.2; = p.L213P on NM_030817.3) | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58733139; called by muse, mutect2, varscan2
- ARMC4 | c.1874A>T p.K625I | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV59465633; called by muse, mutect2, varscan2
- BCAS3 | c.1732G>T p.E578* (on ENST00000390652 / NM_001353144.2; = p.E563* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as COSV66775862; called by muse, mutect2, varscan2
- BLID | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.069); catalogued as COSV73340267; called by muse, mutect2, varscan2
- BRS3 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101036563; called by muse, mutect2, varscan2
- C7 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57475648; called by muse, mutect2, varscan2
- C8B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64778124; called by muse, mutect2
- CAST | c.628G>T p.A210S (on ENST00000341926; = p.A293S on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.114); catalogued as rs768750024, COSV57786347; called by muse, mutect2, varscan2
- CCDC47 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV56723369; called by muse, mutect2, varscan2
- CCPG1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV60525943; called by muse, mutect2, varscan2
- CDH8 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV54874249, COSV54888257; called by muse, mutect2, varscan2
- CDRT1 | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 30/207 reads (14%) | catalogued as COSV55412097; called by muse, mutect2, varscan2
- CFAP58 | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV63834591; called by muse, mutect2, varscan2
- CLECL1 | c.298T>G p.F100V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59931536; called by muse, mutect2, varscan2
- CLTA | c.655G>A p.D219N (on ENST00000242285 / NM_007096.4; = p.D189N on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450092937, COSV54254965; called by muse, mutect2
- COL11A1 | c.2754+2T>C p.X918_splice | Splice Site (SNP) | VAF 25/130 reads (19%) | catalogued as COSV62186454; called by muse, mutect2, varscan2
- COL12A1 | c.3271A>G p.R1091G | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59398310; called by muse, mutect2, varscan2
- COL1A2 | c.2021C>A p.A674D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.357); catalogued as COSV51960075; called by muse, mutect2, varscan2
- COLGALT1 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV53109822; called by muse, mutect2, varscan2
- CPED1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60004746; called by muse, mutect2, varscan2
- CROCC | c.5982G>T p.K1994N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65003857; called by muse, mutect2, varscan2
- CSMD3 | c.5735G>T p.G1912V (on ENST00000297405 / NM_001363185.1; = p.G1808V on NM_052900.3) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52211110; called by muse, mutect2, varscan2
- CSMD3 | c.5734G>T p.G1912* (on ENST00000297405 / NM_001363185.1; = p.G1808* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV52119825, COSV52211131; called by muse, mutect2, varscan2
- CTNND2 | c.2269G>C p.D757H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58896895; called by muse, mutect2, varscan2
- CYP4F12 | c.1279del p.V427Sfs*52 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as COSV61175150; called by pindel, varscan2
- DCTN1 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV62620718; called by muse, mutect2
- DECR2 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs376878406; called by muse, mutect2, varscan2
- DMBT1 | c.6241G>A p.D2081N (on ENST00000338354 / NM_001377530.1; = p.D1324N on NM_004406.3) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.946); catalogued as rs369454959; called by muse, mutect2, varscan2
- DNAH2 | c.7285G>C p.V2429L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV66720969; called by muse, mutect2, varscan2
- DNAH3 | c.6265C>A p.L2089I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV54528888; called by muse, mutect2, varscan2
- ENPP3 | c.1012-1G>C p.X338_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV62954739; called by muse, mutect2, varscan2
- ESAM | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs771286783, COSV54035389, COSV99631586; called by muse, mutect2, varscan2
- EXOC1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.071); catalogued as COSV62120637; called by muse, mutect2, varscan2
- EXT1 | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs551552671, COSV65481003; called by muse, mutect2, varscan2
- F11 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53007310; called by muse, mutect2, varscan2
- FASN | c.3638C>T p.P1213L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100148371, COSV60756340; called by muse, mutect2
- FSCB | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1210911861, COSV61218503; called by muse, mutect2, varscan2
- FSHR | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs267599404, COSV58623080, COSV58625913; called by muse, mutect2, varscan2
- GABRA1 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50107813; called by muse, varscan2
- GANC | c.2737A>T p.I913F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | PolyPhen benign (0.021); catalogued as COSV58809560; called by muse, mutect2
- GAP43 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as rs887982973, COSV100525463, COSV59345134; called by muse, mutect2, varscan2
- GLI3 | c.2329C>G p.H777D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV67889882; called by muse, mutect2, varscan2
- GLI3 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs777201681, COSV67889886; called by muse, mutect2, varscan2
- GNMT | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254504866, COSV55102878; called by muse, mutect2, varscan2
- GPATCH1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1265587580, COSV50117394; called by muse, mutect2, varscan2
- GPR180 | c.780G>C p.L260F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65385721; called by muse, mutect2
- GRIK2 | c.688T>G p.C230G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59743541; called by muse, mutect2, varscan2
- GSTM3 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs1803686, COSV56662438; called by muse, mutect2, varscan2
- GTSF1L | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65932632; called by muse, mutect2, varscan2
- GUCY1A1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56650746, COSV56652608; called by muse, mutect2, varscan2
- GULP1 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV63068771; called by muse, mutect2, varscan2
- H2BC10 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs774417051, COSV59953151; called by muse, mutect2, varscan2
- H2BC17 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58152144, COSV58152931; called by muse, varscan2
- HOXC10 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV57726534; called by muse, mutect2, varscan2
- HTR2C | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52215115; called by muse, mutect2, varscan2
- HYDIN | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55488381; called by muse, mutect2, varscan2
- IGHMBP2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV54823316; called by muse, mutect2, varscan2
- IKZF3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53103319; called by muse, mutect2, varscan2
- IQGAP3 | c.2411G>A p.W804* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100752301, COSV63252337; called by muse, mutect2
- KCNAB1 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV67487510; called by muse, mutect2
- KCNH4 | c.1685G>T p.R562M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52918537; called by muse, mutect2, varscan2
- KCNH6 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.812); catalogued as rs997761060, COSV59004405, COSV59008020; called by muse, mutect2, varscan2
- KCTD1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 198/321 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV58687589; called by muse, mutect2, varscan2
- KLHL4 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV64143757; called by muse, mutect2, varscan2
- KPNA4 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62075996; called by muse, mutect2, varscan2
- KRTAP1-3 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV60336349; called by muse, mutect2, varscan2
- KTN1 | c.3733T>C p.Y1245H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs537088531, COSV58540526; called by muse, mutect2
- LAP3 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56900233; called by muse, mutect2, varscan2
- LHCGR | c.1337C>A p.T446N | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54298473; called by muse, mutect2
- LRP1B | c.1176C>A p.D392E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV67234499; called by muse, mutect2
- LRRIQ1 | c.1910C>A p.S637* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV67832561; called by muse, mutect2, varscan2
- LRRTM3 | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63667139; called by muse, mutect2, varscan2
- LUM | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57128073, COSV57128196; called by muse, mutect2, varscan2
- MEGF6 | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.574); catalogued as rs748457151, COSV62993464; called by muse, mutect2, varscan2
- MMP16 | c.1726T>C p.C576R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54170695; called by muse, varscan2
- MMS22L | c.3127G>T p.D1043Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV51522211; called by muse, mutect2, varscan2
- MPIG6B | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.201); catalogued as COSV65389816; called by muse, mutect2, varscan2
- MSTN | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53621343; called by muse, mutect2, varscan2
- MTNR1B | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57066920, COSV99925256; called by muse, mutect2, varscan2
- MTX1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs768575109, COSV57427018; called by muse, mutect2, varscan2
- MYL9 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54072591; called by muse, mutect2
- MYOM3 | c.4249A>G p.T1417A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs775387849, COSV58395416; called by muse, mutect2
- NETO1 | c.1118T>A p.V373D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55008469; called by muse, mutect2, varscan2
- NEUROD6 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV51772075; called by muse, mutect2, varscan2
- NOTCH3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV54637881; called by muse, mutect2
- NOVA1 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.143); catalogued as COSV57479405; called by muse, mutect2
- NUP214 | c.5485G>A p.A1829T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.399); catalogued as COSV63910434; called by muse, mutect2, varscan2
- OOSP2 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53929185, COSV53930152; called by muse, mutect2
- OR12D2 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.281); catalogued as COSV65828460; called by muse, mutect2, varscan2
- OR2B3 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65851013; called by muse, mutect2, varscan2
- OR2M7 | c.928T>C p.S310P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV58739418; called by muse, mutect2
- OR4S1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369830806, COSV60679044, COSV60679094; called by muse, mutect2, varscan2
- OR52N5 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs755500369, COSV57699033; called by muse, mutect2, varscan2
- OR6K6 | c.601C>A p.Q201K (on ENST00000368144; = p.Q177K on NM_001005184.1) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs375044145; called by muse, mutect2, varscan2
- OR8H1 | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57294550; called by muse, mutect2, varscan2
- OR9A2 | c.872A>T p.D291V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63306747, COSV63306874; called by muse, mutect2, varscan2
- OSBP2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548187834, COSV60239437; called by muse, mutect2, varscan2
- PATJ | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.365); catalogued as rs1294042600, COSV57164566; called by muse, mutect2, varscan2
- PCDHB2 | c.899C>A p.S300* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV50575108, COSV50582171; called by muse, mutect2
- PCDHB4 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.028); catalogued as COSV52023581; called by muse, mutect2, varscan2
- PCLO | c.13390C>T p.P4464S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV61642073; called by muse, mutect2, varscan2
- PDE11A | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); catalogued as rs767044845, COSV53697947; called by muse, mutect2, varscan2
- PHACTR3 | c.1328A>C p.K443T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63029604; called by muse, mutect2, varscan2
- PHC3 | c.2531C>T p.P844L (on ENST00000494943 / NM_001308116.2; = p.P856L on NM_024947.4) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV71948893; called by muse, mutect2, varscan2
- PHLPP2 | c.919T>A p.S307T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV62425012; called by muse, mutect2, varscan2
- PLPPR3 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62459618, COSV62460508; called by muse, mutect2, varscan2
- POU3F4 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as CD093383, COSV64539637; called by muse, mutect2, varscan2
- PPARGC1A | c.2081G>T p.R694M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV53529112; called by muse, mutect2, varscan2
- PRDM9 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV57007959; called by muse, varscan2
- PXDNL | c.3992T>C p.M1331T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62490158; called by muse, mutect2, varscan2
- REG3G | c.208A>T p.K70* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as COSV55450163; called by muse, mutect2, varscan2
- RIMS2 | c.4700C>T p.P1567L (on ENST00000666250 / NM_001348490.2; = p.P1138L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51691747; called by muse, mutect2, varscan2
- RNF43 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV68458639; called by muse, mutect2, varscan2
- SATB2 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); catalogued as COSV53486111; called by muse, mutect2
- SATB2 | c.1880G>C p.G627A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV53486123, COSV53487850; called by mutect2, varscan2
- SECISBP2 | c.760_764del p.L254Kfs*14 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1220219239; called by mutect2, pindel, varscan2
- SERPINA3 | c.446T>A p.L149Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV67586404; called by muse, mutect2, varscan2
- SERPINA7 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59666138; called by muse, mutect2
- SGCZ | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1299102424, COSV66020859; called by mutect2, varscan2
- SGK1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52804069; called by muse, mutect2, varscan2
- SIM1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.057); catalogued as COSV53492467; called by muse, mutect2, varscan2
- SLC13A1 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV52013000; called by muse, mutect2, varscan2
- SLC39A10 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV62767970; called by muse, mutect2, varscan2
- SLC46A2 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV100953447, COSV65290097; called by mutect2, varscan2
- SLC9A4 | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54835263; called by muse, mutect2, varscan2
- SLITRK5 | c.1517A>T p.N506I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61522901, COSV61523562; called by muse, mutect2, varscan2
- SNRPN | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57597726; called by muse, mutect2, varscan2
- SORBS2 | c.2255C>A p.P752Q | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144923775, COSV53003719; called by muse, mutect2, varscan2
- SORCS3 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63813507; called by muse, mutect2, varscan2
- SPAG17 | c.887G>A p.W296* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV60461106; called by muse, mutect2, varscan2
- SPART | c.196C>G p.H66D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.172); catalogued as COSV62086167; called by muse, mutect2, varscan2
- STON1 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59132062; called by muse, mutect2, varscan2
- SYNE1 | c.11414G>T p.R3805L (on ENST00000367255 / NM_182961.4; = p.R3790L on NM_033071.3) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- TAS2R9 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 97/149 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53689199; called by muse, mutect2, varscan2
- TBX18 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV63736337, COSV63737210; called by muse, mutect2, varscan2
- TENM4 | c.5855G>T p.R1952L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53637844, COSV53664320; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51513220; called by muse, mutect2, varscan2
- TGIF2LX | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52213571, COSV99383312; called by muse, mutect2, varscan2
- THSD7B | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55699621, COSV55707214; called by muse, mutect2, varscan2
- TIAM2 | c.2214+1G>T p.X738_splice | Splice Site (SNP) | VAF 25/120 reads (21%) | catalogued as COSV59696316; called by muse, mutect2, varscan2
- TNPO2 | c.2284A>G p.K762E | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV63508694; called by muse, mutect2, varscan2
- TPTE2 | c.1015G>A p.E339K (on ENST00000400230 / NM_199254.2; = p.E262K on NM_130785.3) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs140738972, COSV55015799; called by muse, mutect2, varscan2
- TRBV19 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs763835129; called by muse, mutect2, varscan2
- TRDN | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV62124058; called by muse, mutect2, varscan2
- TRPA1 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV51564445; called by muse, mutect2, varscan2
- TTN | c.22228G>T p.G7410* (on ENST00000591111; = p.G6483* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV60012459, COSV60132496; called by muse, mutect2
- TTN | c.19877T>C p.M6626T (on ENST00000591111; = p.M5699T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | PolyPhen benign (0); catalogued as COSV60132510; called by muse, mutect2, varscan2
- USP54 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV60443964; called by muse, mutect2, varscan2
- UTP3 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV54661282; called by muse, mutect2, varscan2
- VCAN | c.2540C>A p.T847N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54107811; called by muse, mutect2, varscan2
- VEPH1 | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1035663090, COSV62879733; called by muse, mutect2, varscan2
- WDR17 | c.3686A>C p.Y1229S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54576209; called by muse, mutect2, varscan2
- WDR72 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV64748697; called by muse, mutect2, varscan2
- WIF1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.378); catalogued as rs768447787, COSV54132739; called by muse, mutect2, varscan2
- WIF1 | c.546C>A p.C182* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54132757; called by muse, mutect2, varscan2
- XDH | c.42+2T>A p.X14_splice | Splice Site (SNP) | VAF 83/157 reads (53%) | catalogued as COSV101052196; called by muse, mutect2, varscan2
- XIRP1 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61139119; called by muse, mutect2, varscan2
- ZFP42 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58817898; called by muse, mutect2, varscan2
- ZKSCAN4 | c.759T>A p.H253Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.163); catalogued as COSV66023613; called by muse, mutect2, varscan2
- ZMIZ1 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1198193279, COSV57897847; called by muse, mutect2, varscan2
- ZNF180 | c.1627C>G p.H543D | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55421921; called by muse, mutect2
- ZNF248 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61997911; called by muse, mutect2, varscan2
- ZNF3 | c.618C>G p.S206R | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV52796062; called by muse, mutect2
- ZNF3 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 12/237 reads (5%) | catalogued as COSV52795766, COSV52796069; called by muse, mutect2
- ZNF385D | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs756012663, COSV55760056; called by muse, mutect2, varscan2
- ZNF585A | c.296A>T p.E99V (on ENST00000292841 / NM_001288800.2; = p.E44V on NM_152655.3) | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV53062598, COSV53064639; called by muse, mutect2
- ZNF800 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | catalogued as COSV56177249; called by muse, mutect2, varscan2
- ZNF804A | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56451813, COSV56453578; called by muse, mutect2, varscan2
- ZSCAN4 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV56593432; called by muse, mutect2
- ATP11A | c.3321_3322del p.R1107Sfs*4 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by pindel, varscan2
- IGLV1-44 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUTM1 | c.837_838del p.F279Lfs*2 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- PHIP | c.4152_4153insTAA p.D1384_V1385ins* | Nonsense Mutation (INS) | VAF 7/52 reads (13%) | called by mutect2, pindel*, varscan2
- SUPT20HL1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRBV4-1 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA4 | c.3891C>T p.V1297= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV64674445; called by muse, mutect2
- ACSM1 | c.429C>T p.I143= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54636901; called by muse, mutect2, varscan2
- ACTN3 | c.2436A>T p.A812= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV59749231; called by muse, mutect2, varscan2
- ADGRL1 | c.3609C>T p.L1203= (on ENST00000340736 / NM_001008701.3; = p.L1198= on NM_014921.5) | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV61565154; called by muse, mutect2, varscan2
- CACUL1 | c.105C>T p.P35= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV60995012; called by muse, mutect2
- CD96 | c.1194C>T p.T398= (on ENST00000283285 / NM_198196.3; = p.T382= on NM_005816.5) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV51917743; called by muse, mutect2, varscan2
- COLGALT1 | c.1449C>T p.R483= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs370763953; called by muse, mutect2, varscan2
- CXCR2 | c.744G>A p.R248= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as rs754191135, COSV59281011; called by muse, mutect2, varscan2
- CYP2A13 | c.774G>T p.T258= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as rs1338922624, COSV57838440, COSV57839716; called by muse, mutect2, varscan2
- DDB1 | c.1968C>A p.P656= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV57103690; called by muse, mutect2
- EYA4 | c.63T>A p.V21= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV62054242; called by muse, mutect2, varscan2
- FBLN7 | c.1293C>A p.T431= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV55616512; called by muse, mutect2, varscan2
- GATA3 | c.1263G>T p.P421= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV60518783, COSV60519740; called by muse, mutect2, varscan2
- GLI1 | c.2253G>T p.L751= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV57363606; called by muse, mutect2, varscan2
- IFIT3 | c.1011G>A p.E337= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs746479803, COSV51079375; called by muse, mutect2, varscan2
- KCNN2 | c.1488A>G p.L496= (on ENST00000264773; = p.L708= on NM_021614.4) | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV53291355; called by muse, mutect2, varscan2
- KHDRBS2 | c.723T>C p.G241= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV55463317; called by muse, mutect2, varscan2
- KIF4A | c.1939C>A p.R647= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV65543988; called by muse, mutect2, varscan2
- KRTAP6-1 | c.165C>T p.S55= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1568898914, COSV58168505; called by muse, mutect2, varscan2
- LAMC3 | c.2460C>T p.A820= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs1055291211, COSV63092444; called by muse, mutect2
- LRP10 | c.90C>T p.D30= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV62078437; called by muse, mutect2, varscan2
- MAB21L3 | c.795C>T p.H265= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs886564306, COSV65674022; called by muse, mutect2
- NAV3 | c.1332T>A p.P444= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV57087535; called by muse, mutect2, varscan2
- NFIX | c.333G>A p.K111= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV62178180; called by muse, mutect2, varscan2
- NPHS1 | c.2580C>T p.T860= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs545068152, COSV100800137, COSV62288442; called by muse, mutect2, varscan2
- NUP98 | c.564T>C p.C188= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV61433696; called by muse, mutect2, varscan2
- OPRK1 | c.723C>T p.I241= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV55571312; called by muse, mutect2, varscan2
- OR2D3 | c.123C>A p.I41= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV58573238; called by muse, mutect2, varscan2
- OR2T1 | c.306C>G p.L102= | Silent (SNP) | VAF 59/165 reads (36%) | catalogued as rs753213554, COSV63542215; called by muse, mutect2, varscan2
- OR3A1 | c.465T>C p.A155= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs1408859011, COSV60163285; called by muse, mutect2, varscan2
- OR5H6 | c.132C>T p.F44= (on ENST00000642105; = p.F28= on NM_001005479.2) | Silent (SNP) | VAF 42/249 reads (17%) | catalogued as COSV67351642; called by muse, mutect2, varscan2
- OR8I2 | c.666A>T p.S222= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV56167091; called by muse, mutect2, varscan2
- PCARE | c.2523A>G p.K841= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV59055506; called by muse, mutect2
- PLXNC1 | c.1734C>T p.F578= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as rs760549221, COSV51577049; called by muse, mutect2, varscan2
- QTRT1 | c.702G>A p.E234= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51551768; called by muse, mutect2, varscan2
- R3HDM2 | c.1446G>A p.T482= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100715699, COSV61288612; called by muse, mutect2, varscan2
- SGCD | c.402T>C p.Y134= (on ENST00000435422 / NM_001128209.2; = p.Y135= on NM_000337.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs569852808, COSV61910372; called by mutect2, varscan2
- SLC4A4 | c.795G>C p.P265= (on ENST00000264485 / NM_001098484.3; = p.P221= on NM_003759.4) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52625014, COSV52627450; called by muse, mutect2, varscan2
- SLIT1 | c.1068C>T p.L356= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56591285; called by muse, mutect2, varscan2
- SLITRK3 | c.840C>T p.L280= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs376735384, COSV99579798; called by muse, mutect2, varscan2
- SPTA1 | c.4306C>A p.R1436= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV63751852, COSV63754974; called by muse, mutect2, varscan2
- TIAL1 | c.60G>T p.V20= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV64843320; called by muse, mutect2, varscan2
- TM2D1 | c.18G>T p.P6= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV53906551, COSV53907297; called by muse, mutect2, varscan2
- TRANK1 | c.2355C>T p.F785= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs780350521, COSV57146463; called by muse, mutect2, varscan2
- TRHR | c.426C>A p.A142= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61234843; called by muse, mutect2, varscan2
- USP6 | c.162G>A p.T54= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs369687160; called by muse, mutect2, varscan2
- VPS13A | c.9102G>A p.E3034= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100652832, COSV62431868; called by muse, mutect2
- VPS50 | c.2580A>G p.V860= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV59919444; called by muse, mutect2, varscan2
- WDR17 | c.2109T>A p.I703= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV54576197; called by muse, mutect2, varscan2
- FAM27E5 | n.308T>G | RNA (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- THSD4 | c.1016-70489T>A | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- TNIK | c.2406+469A>T | Intron (SNP) | VAF 8/222 reads (4%) | catalogued as COSV52685306; called by muse, mutect2
- TRIB2 | c.563+1125G>C | Intron (SNP) | VAF 61/612 reads (10%) | catalogued as rs531800454, COSV99331087; called by muse, mutect2
- ZNF655 | c.136+1676T>G | Intron (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99402116; called by muse, mutect2, varscan2
